MMRF case MMRF_2328 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6ce3b375-59a3-49fc-9d6f-1670450d4cf1

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.4 years (24,245 days); ISS stage: III; Days to last known disease status: 824 days (2.3 years); Days to last follow up: 824 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 35 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 272 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 53 days; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 63 days; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 74 days; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 137 days; Days to treatment end: 165 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 207 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 357 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 221 days; Days to treatment end: 272 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 273 days; Days to treatment end: 273 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 312 days; Days to treatment end: 354 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 385 days (1.1 years); Days to treatment end: 385 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 426 days (1.2 years); Days to treatment end: 572 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 690 days (1.9 years); Days to treatment end: 774 days (2.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 813 days (2.2 years); Days to treatment end: 823 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 824 days (2.3 years); Days to treatment end: 858 days (2.3 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 824 days (2.3 years); Days to treatment end: 879 days (2.4 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 866 days (2.4 years); Days to treatment end: 867 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 880 days (2.4 years); Days to treatment end: 883 days (2.4 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 908 days (2.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 6.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 85.3 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 6.45 µg/mL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 4.71 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.95 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 221 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 29 g/L; Total Protein 12.4 g/dL; Glucose 4.29 mmol/L; C-Reactive Protein 0.35 mg/dL.
- Day 95: M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 23.1 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.94 g/L; Beta 2 Microglobulin 3.75 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 6.22 mmol/L.
- Day 179 (ECOG 0): M Protein 1.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 21.1 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.93 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 5.28 mmol/L.
- Day 273 (ECOG 0): M Protein 1.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 21 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 3.18 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 8.2 g/dL; Glucose 5.23 mmol/L.
- Day 354 (ECOG 0): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 20.3 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.8 g/L; Beta 2 Microglobulin 3.58 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.45 mmol/L.
- Day 454 (ECOG 0): M Protein 0.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.32 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 1.63 g/L; Beta 2 Microglobulin 3.03 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.45 mmol/L.
- Day 545 (ECOG 1): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 9.21 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.93 g/L; Beta 2 Microglobulin 3.44 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 6.16 mmol/L.
- Day 648 (ECOG 1): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 1.2 g/L; Beta 2 Microglobulin 2.41 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 4.79 mmol/L.
- Day 727 (ECOG 1): M Protein 1.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.85 mg/dL; Immunoglobulin G 23.6 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 1.19 g/L; Beta 2 Microglobulin 3.76 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 8.1 g/dL; Glucose 6.16 mmol/L.
- Day 824: M Protein 4.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Immunoglobulin G 65 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 9.41 µg/mL; Lactate Dehydrogenase 4.48 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 12.6 ×10⁹/L; Absolute Neutrophil 10.3 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 10.3 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day 0: Weight: 74 kg; Height: 177 cm.

Biospecimens (2 samples)
- Sample MMRF_2328_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2328_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
